Somatic mutation profile of tumor specimen TCGA-12-0775-01A (aliquot TCGA-12-0775-01A-01W-0348-08) from TCGA case TCGA-12-0775, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 75.5 years (27,565 days).
Specimen TCGA-12-0775-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65a8c7e5-a159-410a-91f6-77568bb47908.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-12-0775-10A (Blood Derived Normal), aliquot TCGA-12-0775-10A-01W-0348-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad893105-43cd-4ae8-bf96-4597e2eb1922

The open-access MAF lists 113 somatic variants for this specimen: 79 protein-altering or splice-affecting, 33 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 70, Silent 33, Nonsense Mutation 5, Splice Region 1, Splice Site 1, 5'UTR 1, Frame Shift Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARL8B | c.497A>G p.E166G | Missense Mutation (SNP) | VAF 103/340 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.699); catalogued as COSV99848624; called by muse, varscan2
- ARSH | c.271G>T p.G91C | Missense Mutation (SNP) | VAF 80/857 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101139839; called by muse, mutect2
- CARF | c.1370T>G p.V457G | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV100247640; called by muse, mutect2, varscan2
- CCNT2 | c.764G>T p.R255L | Missense Mutation (SNP) | VAF 16/245 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV99750612; called by muse, mutect2
- CD163L1 | c.208G>A p.G70R | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV58011611; called by mutect2, varscan2
- CD19 | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 54/161 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV100218114; called by muse, mutect2, varscan2
- CDC25A | c.1163C>T p.P388L | Missense Mutation (SNP) | VAF 40/1072 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100207450, COSV100207625; called by muse, mutect2
- CFAP58 | c.800A>G p.N267S | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.067); catalogued as COSV100458922; called by muse, mutect2
- CHRM3 | c.1484C>T p.A495V | Missense Mutation (SNP) | VAF 23/352 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs903730617, COSV55082398; called by muse, mutect2
- CNTLN | c.2583C>G p.S861R | Missense Mutation (SNP) | VAF 50/258 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV99263968; called by muse, varscan2
- CRISPLD2 | c.1465G>A p.A489T | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV99295627; called by muse, mutect2, varscan2
- CTCF | c.1772C>T p.T591M | Missense Mutation (SNP) | VAF 81/373 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.165); catalogued as rs139828150, COSV50548440; called by muse, mutect2, varscan2
- CUL9 | c.2180+1G>T p.X727_splice | Splice Site (SNP) | VAF 35/183 reads (19%) | catalogued as COSV99335343; called by muse, mutect2, varscan2
- DCC | c.1257G>T p.K419N | Missense Mutation (SNP) | VAF 156/404 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100499870; called by muse, mutect2, varscan2
- DDC | c.808G>A p.V270I | Missense Mutation (SNP) | VAF 99/466 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.092); catalogued as rs150447169; called by muse, mutect2, varscan2
- DMXL2 | c.8047G>A p.D2683N | Missense Mutation (SNP) | VAF 10/155 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV99196333; called by muse, mutect2
- DNAH7 | c.6173C>A p.P2058H | Missense Mutation (SNP) | VAF 15/276 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100415082, COSV56787000; called by muse, mutect2
- DOK6 | c.437C>T p.T146I | Missense Mutation (SNP) | VAF 89/446 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.735); catalogued as rs532540997, COSV66926121; called by muse, mutect2, varscan2
- DUXA | c.244G>T p.E82* | Nonsense Mutation (SNP) | VAF 28/269 reads (10%) | catalogued as COSV101617139; called by muse, mutect2
- EGFLAM | c.1821G>T p.L607F | Missense Mutation (SNP) | VAF 401/1573 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100380254; called by muse, mutect2, varscan2
- EIF3A | c.2867G>A p.R956Q | Missense Mutation (SNP) | VAF 10/230 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as rs1373174427, COSV64960956; called by muse, mutect2
- ENAM | c.1166G>T p.G389V | Missense Mutation (SNP) | VAF 23/468 reads (5%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.984); catalogued as COSV101253083; called by muse, mutect2
- ENO1 | c.385C>G p.P129A | Missense Mutation (SNP) | VAF 45/184 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.425); catalogued as COSV52303002; called by mutect2, varscan2
- ENOX2 | c.1024G>T p.A342S (on ENST00000338144 / NM_001382520.1; = p.A313S on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.069); catalogued as rs749365956, COSV57652229, COSV57655915; called by mutect2, varscan2
- ESPL1 | c.2599C>A p.L867I | Missense Mutation (SNP) | VAF 14/249 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV99229274; called by muse, mutect2
- FAT4 | c.9539G>C p.C3180S | Missense Mutation (SNP) | VAF 53/477 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.316); catalogued as COSV100628525; called by muse, mutect2, varscan2
- FLNB | c.3824G>A p.G1275E | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV55875863, COSV99913023; called by muse, mutect2, varscan2
- FSIP1 | c.1122G>T p.E374D | Missense Mutation (SNP) | VAF 118/1066 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100618079; called by muse, mutect2, varscan2
- GALNT17 | c.1286G>A p.G429D | Missense Mutation (SNP) | VAF 60/283 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100353852; called by muse, mutect2, varscan2
- GAPDHS | c.31G>A p.V11I | Missense Mutation (SNP) | VAF 156/177 reads (88%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); catalogued as rs759333848, COSV99722776; called by muse, mutect2, varscan2
- GPRC5A | c.26G>A p.C9Y | Missense Mutation (SNP) | VAF 49/278 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99185561; called by muse, mutect2, varscan2
- HASPIN | c.2209C>T p.H737Y | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); catalogued as rs1449370212, COSV99560912; called by muse, mutect2, varscan2
- HERC5 | c.1166C>T p.P389L | Missense Mutation (SNP) | VAF 51/409 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99987672, COSV99987987; called by muse, varscan2
- KDM5C | c.3046C>A p.L1016M | Missense Mutation (SNP) | VAF 16/322 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100949125; called by muse, mutect2
- KIF18A | c.2395C>T p.R799W | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs193161481, COSV54180754; called by muse, mutect2, varscan2
- KIF4B | c.493G>T p.E165* | Nonsense Mutation (SNP) | VAF 22/318 reads (7%) | catalogued as COSV101469280; called by muse, mutect2
- KPRP | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as COSV100908699, COSV64222178; called by muse, mutect2
- KRTAP10-8 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 36/60 reads (60%) | SIFT tolerated (0.31); PolyPhen benign (0.039); catalogued as rs1555931244, COSV58166036; called by muse, mutect2, varscan2
- LAMA3 | c.3591G>T p.K1197N | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as COSV100556772; called by muse, mutect2
- LMAN1L | c.563G>C p.R188T | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.187); catalogued as COSV100547688; called by muse, mutect2, varscan2
- LPP | c.1490C>T p.P497L | Missense Mutation (SNP) | VAF 52/955 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100447058; called by muse, mutect2
- LRP2 | c.11324G>A p.R3775Q | Missense Mutation (SNP) | VAF 98/592 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.069); catalogued as rs779480228, COSV55544173; called by muse, mutect2, varscan2
- MNDA | c.751G>C p.V251L | Missense Mutation (SNP) | VAF 223/2339 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV100933329; called by muse, mutect2
- MUCL1 | c.256G>T p.G86C | Missense Mutation (SNP) | VAF 298/782 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.263); catalogued as COSV100446015; called by muse, varscan2
- NTRK3 | c.1639G>A p.G547R | Missense Mutation (SNP) | VAF 487/1371 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100712177; called by muse, mutect2, varscan2
- NUDC | c.561C>A p.F187L | Missense Mutation (SNP) | VAF 26/192 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0.014); catalogued as COSV100345540; called by muse, mutect2, varscan2
- RAI2 | c.721C>T p.P241S | Missense Mutation (SNP) | VAF 12/338 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100518306; called by muse, mutect2
- RBM15 | c.1685G>A p.R562K | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.122); catalogued as rs1319923343, COSV100873439; called by muse, mutect2
- RBM46 | c.377T>C p.I126T | Missense Mutation (SNP) | VAF 70/617 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV99908077; called by muse, mutect2, varscan2
- RHNO1 | c.217C>T p.Q73* | Nonsense Mutation (SNP) | VAF 24/129 reads (19%) | catalogued as rs1189355291, COSV100817038; called by muse, mutect2, varscan2
- SLC17A2 | c.389C>A p.S130Y | Missense Mutation (SNP) | VAF 34/520 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99614320; called by muse, mutect2
- SLC1A6 | c.823T>C p.S275P | Missense Mutation (SNP) | VAF 971/1369 reads (71%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV99693709; called by muse, mutect2, varscan2
- SLC25A40 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV100353665; called by muse, mutect2, varscan2
- SLC9A4 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 45/175 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV99762992; called by muse, mutect2, varscan2
- SNX25 | c.748G>T p.A250S | Missense Mutation (SNP) | VAF 17/592 reads (3%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.514); catalogued as COSV53016448, COSV99252806; called by muse, mutect2
- SPZ1 | c.30G>A p.M10I | Missense Mutation (SNP) | VAF 986/2021 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.077); catalogued as COSV57064988, COSV99698151; called by muse, mutect2, varscan2
- ST3GAL2 | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 8/48 reads (17%) | PolyPhen probably damaging (0.918); catalogued as COSV100735612; called by muse, varscan2
- STIM2 | c.676A>G p.I226V | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.194); catalogued as COSV99402584; called by muse, mutect2, varscan2
- STPG1 | c.28C>T p.R10C (on ENST00000337248 / NM_001199013.2; = p.N2= on NM_178122.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/190 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.092); catalogued as rs377495393, COSV50219156; called by muse, mutect2, varscan2
- SYCP1 | c.1806C>A p.N602K | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.895); catalogued as COSV101050925; called by muse, mutect2
- TAF1L | c.1230C>A p.S410R | Missense Mutation (SNP) | VAF 234/1304 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99644617; called by muse, varscan2
- TIAM1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 168/835 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as COSV99734894, COSV99737436; called by muse, mutect2, varscan2
- TTI1 | c.136C>G p.Q46E | Missense Mutation (SNP) | VAF 69/176 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100989634; called by muse, mutect2, varscan2
- UBE2J1 | c.448G>T p.E150* | Nonsense Mutation (SNP) | VAF 59/149 reads (40%) | catalogued as COSV101470248; called by muse, mutect2, varscan2
- UGT2B4 | c.1060T>C p.Y354H | Missense Mutation (SNP) | VAF 137/1293 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100522402; called by muse, mutect2, varscan2
- UPK3A | c.731C>T p.T244M | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as rs374008042; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USP34 | c.8499C>A p.Y2833* | Nonsense Mutation (SNP) | VAF 22/392 reads (6%) | catalogued as COSV101276991; called by muse, mutect2
- USP34 | c.400C>G p.L134V | Missense Mutation (SNP) | VAF 18/555 reads (3%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV101276993; called by muse, mutect2
- USP53 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 99/1124 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV99917572; called by muse, mutect2
- XDH | c.692G>A p.G231E | Missense Mutation (SNP) | VAF 230/606 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101052191; called by muse, mutect2, varscan2
- ZNF804A | c.2072A>T p.N691I | Missense Mutation (SNP) | VAF 123/347 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.125); catalogued as COSV100167711; called by muse, mutect2, varscan2
- ZNF808 | c.2533A>G p.K845E | Missense Mutation (SNP) | VAF 15/522 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV100707919; called by muse, mutect2
- AKAP13 | c.3257_3306del p.D1086Afs*41 | Frame Shift Del (DEL) | VAF 96/862 reads (11%) | called by mutect2, pindel
- CCDC191 | c.329A>G p.E110G | Missense Mutation (SNP) | VAF 181/717 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.022); called by mutect2, varscan2
- CDK9 | c.484G>C p.V162L | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.322); called by mutect2, varscan2
- MBOAT2 | c.507G>A p.R169= | Splice Region (SNP) | VAF 10/188 reads (5%) | called by muse, mutect2
- PHKG2 | c.254C>A p.A85D | Missense Mutation (SNP) | VAF 16/239 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.009); called by muse, mutect2
- STXBP6 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, varscan2
- TBC1D2 | c.2360T>A p.L787H | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by mutect2, varscan2
- ACKR2 | c.597C>T p.F199= | Silent (SNP) | VAF 8/209 reads (4%) | catalogued as COSV56180172; called by muse, mutect2
- ANXA11 | c.1245C>T p.S415= | Silent (SNP) | VAF 36/114 reads (32%) | catalogued as rs139193001, COSV55417179; called by muse, mutect2, varscan2
- ATRNL1 | c.2649G>A p.A883= | Silent (SNP) | VAF 113/858 reads (13%) | catalogued as rs149670730; called by muse, mutect2, varscan2
- BEND2 | c.201C>T p.G67= | Silent (SNP) | VAF 34/426 reads (8%) | called by mutect2, varscan2
- BRD2 | c.1383G>T p.G461= | Silent (SNP) | VAF 32/882 reads (4%) | catalogued as COSV100875670; called by muse, mutect2
- CACNA1A | c.4422C>T p.D1474= | Silent (SNP) | VAF 40/152 reads (26%) | catalogued as rs374555263; ClinVar: likely benign; called by muse, mutect2, varscan2
- DMD | c.5805C>A p.G1935= | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as COSV100819562; called by muse, mutect2, varscan2
- DRICH1 | c.618C>A p.I206= | Silent (SNP) | VAF 30/352 reads (9%) | catalogued as COSV100497434; called by muse, mutect2
- ERG | c.291C>T p.G97= | Silent (SNP) | VAF 169/587 reads (29%) | catalogued as rs146525668; called by muse, mutect2, varscan2
- HIVEP2 | c.1950C>T p.D650= | Silent (SNP) | VAF 98/191 reads (51%) | catalogued as COSV99173338; called by mutect2, varscan2
- KMT2D | c.3675C>T p.P1225= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV99981307; called by muse, mutect2
- LTBP3 | c.1098C>T p.R366= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV100099596; called by muse, mutect2
- MLPH | c.54C>A p.V18= | Silent (SNP) | VAF 37/116 reads (32%) | catalogued as COSV99222165; called by muse, mutect2, varscan2
- MYCBP2 | c.12087T>C p.P4029= (on ENST00000357337; = p.P4067= on NM_015057.5) | Silent (SNP) | VAF 46/555 reads (8%) | catalogued as COSV100630275; called by muse, mutect2
- NFATC3 | c.906G>A p.R302= | Silent (SNP) | VAF 68/406 reads (17%) | catalogued as COSV60480597; called by muse, mutect2, varscan2
- NIPA1 | c.975T>C p.N325= | Silent (SNP) | VAF 10/289 reads (3%) | called by muse, mutect2
- OR2L8 | c.423G>T p.V141= | Silent (SNP) | VAF 66/1949 reads (3%) | catalogued as rs1479335978, COSV100594204; called by muse, mutect2
- OR5B12 | c.868C>T p.L290= | Silent (SNP) | VAF 12/154 reads (8%) | catalogued as COSV100222414; called by muse, mutect2
- OR5D14 | c.567G>T p.V189= | Silent (SNP) | VAF 42/602 reads (7%) | catalogued as COSV59455582, COSV59459193; called by muse, mutect2
- OTUB2 | c.621G>T p.V207= | Silent (SNP) | VAF 11/85 reads (13%) | catalogued as COSV99180163; called by muse, mutect2, varscan2
- PCDH11X | c.1449C>T p.I483= | Silent (SNP) | VAF 27/150 reads (18%) | catalogued as COSV100008222, COSV100011541; called by muse, varscan2
- PMS2 | c.99G>T p.L33= | Silent (SNP) | VAF 42/579 reads (7%) | catalogued as COSV56150072, COSV99764192; called by muse, mutect2
- PTPRM | c.3987C>A p.R1329= | Silent (SNP) | VAF 19/129 reads (15%) | catalogued as COSV100157046; called by muse, mutect2, varscan2
- RBM15 | c.1683G>A p.L561= | Silent (SNP) | VAF 6/63 reads (10%) | catalogued as COSV100873438; called by muse, mutect2
- RPL30 | c.294T>C p.D98= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV99750424; called by muse, mutect2, varscan2
- SLITRK4 | c.1254A>G p.G418= | Silent (SNP) | VAF 71/251 reads (28%) | catalogued as rs1556427061, COSV100567340, COSV62022260; called by muse, mutect2, varscan2
- SORBS1 | c.3492G>A p.Q1164= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV53356036, COSV99527944; called by muse, varscan2
- SPOCD1 | c.3186C>T p.T1062= | Silent (SNP) | VAF 20/28 reads (71%) | catalogued as COSV99929836; called by muse, varscan2
- TAF2 | c.381C>T p.C127= | Silent (SNP) | VAF 99/703 reads (14%) | catalogued as COSV100978662; called by muse, mutect2, varscan2
- TMEM106A | c.519G>T p.G173= | Silent (SNP) | VAF 20/568 reads (4%) | catalogued as rs1344968247, COSV100357809; called by muse, mutect2
- TMEM86A | c.441G>A p.V147= | Silent (SNP) | VAF 59/76 reads (78%) | catalogued as COSV99773715; called by muse, mutect2, varscan2
- TNIK | c.2040C>T p.S680= | Silent (SNP) | VAF 15/497 reads (3%) | catalogued as rs941776415, COSV99457049; called by muse, mutect2
- WNT2 | c.210C>T p.A70= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as rs139486726; called by muse, mutect2, varscan2
- RUNX2 | c.-24T>A | 5'UTR (SNP) | VAF 61/339 reads (18%) | catalogued as COSV100177073; called by muse, mutect2, varscan2
